Somatic mutation profile of tumor specimen TCGA-IN-A7NR-01A (aliquot TCGA-IN-A7NR-01A-11D-A34U-08) from TCGA case TCGA-IN-A7NR, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 64.1 years (23,415 days).
Specimen TCGA-IN-A7NR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9a116edb-faa2-4212-8cc9-5c5d1af7c1de.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IN-A7NR-10A (Blood Derived Normal), aliquot TCGA-IN-A7NR-10A-01D-A34X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5f913b09-97a6-4a90-9d7b-66b1f6f34ee6

The open-access MAF lists 86 somatic variants for this specimen: 62 protein-altering or splice-affecting, 22 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 57, Silent 22, Splice Site 3, Splice Region 1, 5'Flank 1, Nonsense Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FANCC | c.1663C>T p.R555* | Nonsense Mutation (SNP) | VAF 4/41 reads (10%) | catalogued as rs370974124, CM161678; ClinVar: likely pathogenic / uncertain significance; called by mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 8/60 reads (13%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AC018630.4 | c.161G>A p.R54K | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated, low confidence (0.98); PolyPhen benign (0.025); catalogued as COSV99958505; called by muse, mutect2, varscan2
- AKT3 | c.1311A>C p.E437D | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV99795080; called by muse, mutect2
- APOB | c.2683G>A p.A895T | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.859); catalogued as rs371884333, COSV99265146; called by muse, mutect2
- ASXL3 | c.2164T>G p.L722V | Missense Mutation (SNP) | VAF 26/257 reads (10%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.141); catalogued as COSV99324552; called by muse, mutect2
- AVPR1A | c.455C>T p.A152V | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100146832; called by muse, mutect2, varscan2
- C4A | c.3311C>T p.S1104F | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.056); catalogued as COSV71178211; called by muse, mutect2, varscan2
- CAVIN1 | c.650G>A p.R217H | Missense Mutation (SNP) | VAF 18/148 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100824535; called by muse, mutect2, varscan2
- CCL13 | c.122A>C p.K41T | Missense Mutation (SNP) | VAF 23/150 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV99861713; called by muse, mutect2, varscan2
- CSMD3 | c.4178T>C p.L1393P (on ENST00000297405 / NM_001363185.1; = p.L1289P on NM_052900.3) | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99832026; called by muse, mutect2
- DCAF4L1 | c.512T>C p.V171A | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV100295683; called by muse, mutect2
- DCLRE1C | c.623C>T p.A208V (on ENST00000378278 / NM_001350965.2; = p.A93V on NM_022487.4) | Missense Mutation (SNP) | VAF 25/230 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1326360954, COSV100739789, COSV63185496; called by muse, mutect2, varscan2
- DDIT4L | c.542T>C p.L181P | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56767953; called by muse, mutect2, varscan2
- DDX27 | c.1046G>A p.R349Q | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100874679; called by muse, mutect2, varscan2
- DPP10 | c.835C>G p.Q279E | Missense Mutation (SNP) | VAF 9/176 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV100063136; called by muse, mutect2
- EMC1 | c.931A>G p.S311G | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV100617465; called by muse, mutect2, varscan2
- FAT2 | c.10745C>T p.A3582V | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs771778319, COSV55812423; called by muse, mutect2, varscan2
- FAT4 | c.5419C>T p.R1807C | Missense Mutation (SNP) | VAF 15/140 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746989506, COSV58685052; called by muse, mutect2, varscan2
- FSCB | c.1052T>C p.L351P | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.246); catalogued as COSV100469219; called by muse, mutect2, varscan2
- GABRA1 | c.1229A>T p.K410M | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV99195821; called by muse, mutect2, varscan2
- GRIA3 | c.1551A>C p.E517D | Missense Mutation (SNP) | VAF 16/270 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs751241634, COSV52071707; called by muse, mutect2
- IPPK | c.302G>A p.C101Y | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99845556; called by muse, mutect2, varscan2
- ITGAL | c.1753A>T p.I585F | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); catalogued as COSV100776219; called by muse, mutect2, varscan2
- LRBA | c.6226+1G>C p.X2076_splice | Splice Site (SNP) | VAF 9/89 reads (10%) | catalogued as COSV100841403; called by muse, mutect2, varscan2
- LRP1B | c.10768+1G>A p.X3590_splice | Splice Site (SNP) | VAF 13/162 reads (8%) | catalogued as COSV67281722; called by muse, mutect2
- LRRC7 | c.2081T>G p.L694R (on ENST00000651989 / NM_001370785.2; = p.L661R on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99226167; called by muse, mutect2
- LRRK2 | c.5600A>C p.N1867T | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.391); catalogued as COSV100109929; called by muse, mutect2, varscan2
- MAP2 | c.1200A>C p.E400D | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.007); catalogued as COSV99559401; called by muse, mutect2, varscan2
- MTRF1 | c.647G>A p.C216Y | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99520920; called by muse, mutect2
- NLRP11 | c.2441G>A p.R814H | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV64085555; called by muse, mutect2, varscan2
- NLRP2 | c.587G>T p.S196I | Missense Mutation (SNP) | VAF 16/173 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.13); catalogued as COSV99672201; called by muse, mutect2
- OR2AK2 | c.665T>G p.L222R | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV63556178; called by muse, mutect2
- OR7D2 | c.310T>G p.S104A | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.057); catalogued as COSV100712996; called by muse, mutect2
- OR8B8 | c.652T>G p.Y218D | Missense Mutation (SNP) | VAF 7/118 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100045005; called by muse, mutect2
- OTOGL | c.2272T>C p.C758R (on ENST00000547103; = p.C749R on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101509175; called by muse, mutect2, varscan2
- PAFAH1B1 | c.483C>G p.S161R | Missense Mutation (SNP) | VAF 33/173 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.306); catalogued as COSV101250374; called by muse, mutect2, varscan2
- PLD1 | c.912-1G>T p.X304_splice | Splice Site (SNP) | VAF 17/79 reads (22%) | catalogued as COSV100578026; called by muse, mutect2, varscan2
- PRR19 | c.283C>G p.L95V | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.52); catalogued as COSV100003773, COSV56625940; called by muse, mutect2
- RGS13 | c.446T>G p.L149R | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101232223; called by muse, mutect2, varscan2
- RUNDC1 | c.1810C>T p.R604C | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs749602274, COSV64511705; called by muse, mutect2, varscan2
- SHANK1 | c.848C>T p.P283L | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99520940; called by muse, mutect2, varscan2
- SLC44A4 | c.2011C>T p.L671= | Splice Region (SNP) | VAF 12/109 reads (11%) | catalogued as rs768032825, COSV57665844; called by muse, mutect2, varscan2
- SPRR2G | c.65A>C p.K22T | Missense Mutation (SNP) | VAF 14/76 reads (18%) | PolyPhen possibly damaging (0.785); catalogued as COSV100907381; called by muse, mutect2, varscan2
- TG | c.8159A>G p.K2720R | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.554); catalogued as COSV99600360; called by muse, mutect2, varscan2
- TLR4 | c.1457A>C p.N486T (on ENST00000355622 / NM_138554.5; = p.N446T on NM_003266.4) | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.342); catalogued as COSV100842736; called by muse, mutect2, varscan2
- TMEM209 | c.1258G>A p.G420R | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as COSV100390392; called by muse, mutect2
- TNIK | c.602C>T p.A201V | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.955); catalogued as COSV52675448; called by muse, mutect2
- TNIP3 | c.230C>T p.T77M | Missense Mutation (SNP) | VAF 29/286 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.05); catalogued as COSV50248294; called by muse, mutect2, varscan2
- TRIM49 | c.979A>C p.S327R | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.028); catalogued as COSV61670608; called by muse, mutect2, varscan2
- TRIM49 | c.132A>T p.Q44H | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); catalogued as COSV100316003; called by muse, mutect2, varscan2
- TUSC3 | c.451T>G p.F151V | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.206); catalogued as COSV101141152; called by muse, mutect2
- UPF3B | c.1340G>A p.R447Q (on ENST00000276201 / NM_080632.3; = p.R434Q on NM_023010.3) | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); catalogued as COSV99352112; called by muse, mutect2
- USP16 | c.1834G>A p.D612N | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.937); catalogued as COSV100537908; called by muse, mutect2, varscan2
- XKR7 | c.1145G>A p.R382H | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as rs1444236059, COSV73813499; called by muse, mutect2, varscan2
- ZFHX4 | c.5208G>C p.Q1736H | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.966); catalogued as COSV99261678; called by muse, mutect2, varscan2
- ZMYND8 | c.529G>A p.V177I (on ENST00000311275 / NM_001363741.2; = p.V197I on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.539); catalogued as COSV53695994; called by muse, mutect2, varscan2
- ZNF43 | c.2203A>C p.K735Q | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.842); catalogued as COSV100731786; called by muse, mutect2
- ZNF440 | c.391C>T p.H131Y | Missense Mutation (SNP) | VAF 22/241 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.374); catalogued as COSV100407500; called by muse, mutect2
- ZNF578 | c.1554G>T p.K518N | Missense Mutation (SNP) | VAF 11/122 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV101405041; called by muse, mutect2
- ZNF823 | c.1052A>C p.E351A (on ENST00000341191 / NM_001297610.2; = p.E307A on NM_017507.2) | Missense Mutation (SNP) | VAF 24/151 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV100362475; called by muse, mutect2, varscan2
- WASHC2C | c.3124A>G p.T1042A (on ENST00000336378; = p.T1021A on NM_015262.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/170 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); called by muse, mutect2
- AL592490.1 | c.1086A>G p.K362= | Silent (SNP) | VAF 6/95 reads (6%) | catalogued as COSV69425461, COSV69425526; called by muse, mutect2
- ALG11 | c.306C>T p.T102= | Silent (SNP) | VAF 10/110 reads (9%) | catalogued as rs762974051, COSV73000618; called by muse, mutect2
- ATP1A3 | c.3012C>T p.Y1004= (on ENST00000545399 / NM_001256214.2; = p.Y991= on NM_152296.5) | Silent (SNP) | VAF 4/54 reads (7%) | catalogued as rs372919447; called by muse, mutect2
- BSN | c.8580C>T p.A2860= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as rs747505287, COSV99608140; called by mutect2, varscan2
- CCT6A | c.249C>T p.A83= | Silent (SNP) | VAF 37/203 reads (18%) | catalogued as COSV99303400; called by muse, mutect2, varscan2
- CUL4A | c.316C>T p.L106= (on ENST00000375440 / NM_001008895.4; = p.L6= on NM_003589.3) | Silent (SNP) | VAF 3/37 reads (8%) | catalogued as rs1244011654; called by muse, mutect2
- DDX58 | c.2052A>T p.A684= | Silent (SNP) | VAF 5/62 reads (8%) | catalogued as COSV101152731; called by muse, mutect2
- ETV3 | c.126G>A p.L42= | Silent (SNP) | VAF 5/81 reads (6%) | catalogued as COSV100461054; called by muse, mutect2
- KLHL28 | c.138T>A p.I46= | Silent (SNP) | VAF 15/108 reads (14%) | catalogued as COSV100753083; called by muse, mutect2, varscan2
- KPRP | c.312T>G p.T104= | Silent (SNP) | VAF 33/214 reads (15%) | catalogued as COSV100908693; called by muse, mutect2, varscan2
- LRFN1 | c.1584G>A p.R528= | Silent (SNP) | VAF 3/24 reads (13%) | catalogued as COSV50472144; called by muse, mutect2
- MAP2 | c.2430A>G p.L810= | Silent (SNP) | VAF 13/113 reads (12%) | catalogued as COSV99557822; called by muse, mutect2, varscan2
- MCTP2 | c.1524C>T p.V508= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as rs776556845, COSV59142862; ClinVar: likely benign; called by muse, mutect2, varscan2
- MUC16 | c.3432C>T p.G1144= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as COSV101199523; called by muse, mutect2
- NPR3 | c.1200C>T p.I400= | Silent (SNP) | VAF 31/146 reads (21%) | catalogued as rs778233918, COSV54088871; called by muse, mutect2, varscan2
- OR51Q1 | c.795C>T p.R265= | Silent (SNP) | VAF 13/103 reads (13%) | catalogued as rs1410091789, COSV100332909; called by muse, mutect2, varscan2
- PASK | c.6G>A p.E2= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as COSV99299258; called by muse, mutect2
- PCDHB9 | c.2220C>T p.S740= | Silent (SNP) | VAF 25/231 reads (11%) | called by muse, mutect2, varscan2
- PLD5 | c.1359T>C p.N453= (on ENST00000442594; = p.N391= on NM_001195811.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/78 reads (12%) | catalogued as COSV100139960, COSV59171604; called by muse, mutect2, varscan2
- POU4F2 | c.1056C>T p.I352= | Silent (SNP) | VAF 17/189 reads (9%) | catalogued as rs755801755, COSV55583552; called by muse, mutect2
- PTPRD | c.90C>T p.P30= | Silent (SNP) | VAF 13/77 reads (17%) | catalogued as rs1030414220; ClinVar: likely benign; called by muse, mutect2, varscan2
- SYDE2 | c.2106C>G p.V702= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as COSV99320421; called by muse, mutect2, varscan2
- FOLH1B | n.2004A>C | RNA (SNP) | VAF 12/148 reads (8%) | called by muse, mutect2
- STMP1 | chr7:135660249 C>A | 5'Flank (SNP) | VAF 19/129 reads (15%) | catalogued as rs770522422; called by muse, mutect2, varscan2
